Somatic mutation profile of tumor specimen TCGA-OR-A5LN-01A (aliquot TCGA-OR-A5LN-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LN, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 31.2 years (11,414 days).
Specimen TCGA-OR-A5LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 366c3da2-db0b-49ce-a260-ae14d84be344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LN-10A (Blood Derived Normal), aliquot TCGA-OR-A5LN-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa636df0-ff0c-4b34-a293-6b168655a380

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAH2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549196716, COSV61483335; called by muse, mutect2, varscan2
- DCAF8L1 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as COSV101491527; called by muse, mutect2, varscan2
- KCNK10 | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.931); catalogued as rs1256692147, COSV56638896; called by muse, mutect2, varscan2
- KCNK9 | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100271294; called by muse, mutect2, varscan2
- OR52M1 | c.746G>C p.C249S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100798609; called by muse, mutect2
- SNTN | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- STON2 | c.2596C>A p.H866N (on ENST00000649389 / NM_001366849.2; = p.H809N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VAT1 | c.663C>G p.A221= | Silent (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
